Somatic mutation profile of tumor specimen d6584b4a-ca99-4a2a-8b4e-c8b22e (aliquot d6584b4a-ca99-4a2a-8b4e-c8b22e_D6_1) from CPTAC case 11CO039, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen d6584b4a-ca99-4a2a-8b4e-c8b22e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88572105-96d9-4bf5-8b5f-27786588f2c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b400a501-7308-4808-8d50-40213d (Blood Derived Normal), aliquot b400a501-7308-4808-8d50-40213d_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c94c3f15-4862-4a50-bb19-504cd55d9fd0

The open-access MAF lists 218 somatic variants for this specimen: 150 protein-altering or splice-affecting, 44 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 44, Intron 13, Nonsense Mutation 9, Splice Site 5, 3'UTR 4, Frame Shift Ins 4, 5'Flank 3, Frame Shift Del 3, 5'UTR 3, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 61/116 reads (53%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 189/299 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3724C>T p.P1242S (on ENST00000272895 / NM_173076.3; = p.P924S on NM_015657.3) | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs868391784; called by muse, mutect2, varscan2
- ABHD2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs757210313, COSV100756383, COSV61775010; called by muse, mutect2, varscan2
- ALKBH4 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs901314579; called by muse, mutect2, varscan2
- ALX3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746228217, COSV100873871; called by muse, mutect2
- ANKRD17 | c.920C>G p.A307G | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV58220215; called by muse, mutect2
- AP2M1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1167948297; called by muse, mutect2, varscan2
- APPL2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs770933955, COSV51594951; called by muse, mutect2
- ASAH2 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1334847155; called by muse, mutect2
- CDH18 | c.1552G>T p.A518S | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.101); catalogued as COSV56904539; called by muse, mutect2, varscan2
- CFAP61 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs375931602, COSV99844530; called by muse, mutect2, varscan2
- CLN8 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386834134, CM100116, CM131278, COSV100486070; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISPLD1 | c.1244+1G>T p.X415_splice | Splice Site (SNP) | VAF 54/277 reads (19%) | catalogued as COSV51551028; called by muse, mutect2, varscan2
- CSMD3 | c.3134A>C p.E1045A (on ENST00000297405 / NM_001363185.1; = p.E941A on NM_052900.3) | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.685); catalogued as rs767273053; called by muse, mutect2, varscan2
- CYP2E1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as rs1354838426, COSV99429132; called by muse, mutect2, varscan2
- DCAF8L1 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.173); catalogued as COSV71595141, COSV71595142; called by muse, mutect2, varscan2
- DOCK2 | c.1611A>C p.E537D | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); catalogued as COSV56946243; called by muse, mutect2, varscan2
- EFCAB5 | c.3523G>A p.V1175I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs777618059, COSV57938090; called by muse, mutect2, varscan2
- ERN2 | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891071; called by muse, mutect2, varscan2
- FAT2 | c.9566C>A p.A3189D | Missense Mutation (SNP) | VAF 130/452 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55816524; called by muse, mutect2, varscan2
- FGA | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs750761333, COSV100120244; called by muse, mutect2, varscan2
- GPR34 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569404464; called by muse, mutect2, varscan2
- H2AC11 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.667); catalogued as rs1327855564, COSV60361976; called by muse, mutect2, varscan2
- HERC2 | c.10301C>T p.A3434V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs745417857; called by muse, mutect2, varscan2
- IL1RL2 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51819823; called by muse, mutect2
- LIPA | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs544080483, COSV51080691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LTA | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV101403262; called by muse, mutect2, varscan2
- MBD6 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1340054178; called by muse, mutect2, varscan2
- MDN1 | c.11182C>A p.Q3728K | Missense Mutation (SNP) | VAF 108/352 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV101020973; called by muse, mutect2, varscan2
- MED12L | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs774424420, COSV56370763; called by muse, mutect2, varscan2
- MRGPRE | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67745511; called by muse, mutect2
- MROH1 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 159/962 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs1045133142; called by muse, mutect2, varscan2
- MSH6 | c.3803C>A p.A1268E | Missense Mutation (SNP) | VAF 117/307 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs587779293; called by muse, mutect2, varscan2
- NSDHL | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 142/332 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200068633, COSV64743972; called by mutect2, varscan2
- OR13C9 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs1449453306, COSV52241779, COSV52243398; called by muse, mutect2
- PALM2AKAP2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs766588481; called by muse, mutect2, varscan2
- PLEC | c.11572C>T p.R3858C (on ENST00000322810 / NM_201380.4; = p.R3748C on NM_000445.5) | Missense Mutation (SNP) | VAF 424/840 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as rs782134827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLLP | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as rs149486153; called by muse, mutect2, varscan2
- PROSER1 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs187958429; called by muse, mutect2, varscan2
- RBM18 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as rs1312371590; called by muse, mutect2, varscan2
- REN | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 301/766 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs756122840, COSV99689537; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- RSPH6A | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as rs776692589, COSV99679511; called by muse, mutect2, varscan2
- RTEL1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 98/372 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs748434559; called by muse, mutect2, varscan2
- RYR1 | c.5459G>A p.R1820H | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.695); catalogued as rs750141316; called by muse, mutect2, varscan2
- SELENBP1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs148749661; called by muse, mutect2
- SLC16A2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs748528906; called by muse, mutect2, varscan2
- SLC22A31 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.806); catalogued as rs1335613458; called by muse, mutect2, varscan2
- SNAP91 | c.1484T>G p.L495R | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52134294; called by muse, mutect2, varscan2
- SOX17 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52024603; called by muse, mutect2, varscan2
- STAB1 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771649805, COSV58742683; called by muse, mutect2, varscan2
- TDRD15 | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs1355927874; called by muse, mutect2
- TMC6 | c.891G>A p.A297= | Splice Region (SNP) | VAF 115/318 reads (36%) | catalogued as rs762040968, COSV100130255; called by muse, varscan2
- TNNT2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 206/585 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs770771962; called by muse, mutect2, varscan2
- TRIM5 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.094); catalogued as rs759560671; called by muse, mutect2, varscan2
- TRIM56 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1041968573, COSV100047447; called by muse, mutect2, varscan2
- TRMT9B | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192687145, COSV101501634; called by muse, mutect2, varscan2
- TTN | c.72235A>G p.T24079A (on ENST00000591111; = p.T16655A on NM_003319.4) | Missense Mutation (SNP) | VAF 95/264 reads (36%) | PolyPhen benign (0); catalogued as rs748079783; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 61/154 reads (40%) | catalogued as rs756173793; called by mutect2, varscan2
- ZNF157 | c.1439G>A p.C480Y | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs866086084; called by muse, mutect2, varscan2
- ABCA9 | c.4772A>G p.E1591G | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- ADAM17 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ADAMTS12 | c.1322C>A p.T441N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRV1 | c.18067T>A p.F6023I | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ADGRV1 | c.18068T>A p.F6023Y | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- AMOT | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ATG4A | c.610T>G p.L204V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BRD1 | c.2570C>A p.S857Y (on ENST00000216267 / NM_001349940.1; = p.S988Y on NM_001304808.3) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- C5 | c.679T>A p.F227I | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1A | c.6094G>A p.E2032K | Missense Mutation (SNP) | VAF 108/233 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CALHM6 | c.164T>G p.F55C | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CAPNS2 | c.50A>G p.E17G | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- CCDC18 | c.-2-1G>A | Splice Site (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- CCDC39 | c.2281T>A p.L761I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CDH6 | c.2077G>T p.V693L | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- CEACAM4 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CELSR1 | c.2842G>A p.G948S | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP152 | c.1963C>G p.Q655E | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN17 | c.106G>T p.V36F | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CLN6 | c.666G>T p.W222C | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- COL11A1 | c.2610G>T p.R870= | Splice Region (SNP) | VAF 42/145 reads (29%) | called by muse, mutect2, varscan2
- COPB1 | c.2813T>G p.L938* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- CSE1L | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 100/169 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- DEFB110 | c.90del p.L31* | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- DLGAP1 | c.2695T>C p.W899R | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL2 | c.4012C>T p.H1338Y | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DNAH14 | c.4250T>G p.L1417R (on ENST00000445597; = p.L1822R on NM_001367479.1) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DOCK11 | c.5860C>A p.Q1954K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.97); called by muse, mutect2
- DPP10 | c.2363T>C p.L788P | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPY19L2 | c.2210A>C p.E737A | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DSG2 | c.3129_3144del p.N1043Kfs*4 | Frame Shift Del (DEL) | VAF 170/327 reads (52%) | called by mutect2, varscan2
- DUSP14 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- EP400 | c.9341T>G p.L3114R | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- FAT4 | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 165/457 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- GALK2 | c.476T>G p.L159R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GCFC2 | c.1226G>C p.R409T | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- INTS13 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IREB2 | c.1026_1034dup p.X342_splice | Splice Site (INS) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- IRF4 | c.774C>G p.Y258* | Nonsense Mutation (SNP) | VAF 68/202 reads (34%) | called by muse, mutect2, varscan2
- LRWD1 | c.1564T>G p.C522G | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.091); called by muse, mutect2
- MAPK6 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MDN1 | c.11181T>A p.C3727* | Nonsense Mutation (SNP) | VAF 106/348 reads (30%) | called by muse, mutect2, varscan2
- MTG1 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYL4 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NAT10 | c.1294C>A p.R432S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- NR0B1 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 262/748 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OPRK1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR6K6 | c.563T>G p.I188S (on ENST00000368144; = p.I164S on NM_001005184.1) | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- OSBPL6 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- OTUD4 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- PAK3 | c.775dup p.S259Ffs*6 (on ENST00000262836 / NM_001324328.2; = p.S244Ffs*6 on NM_002578.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 57/247 reads (23%) | called by mutect2, pindel, varscan2
- PARP15 | c.1445T>G p.L482R (on ENST00000464300 / NM_001113523.3; = p.L248R on NM_152615.2) | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PIWIL1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 51/188 reads (27%) | called by muse, mutect2, varscan2
- PLS3 | c.74-1G>C p.X25_splice | Splice Site (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- PLXNB1 | c.4624A>G p.K1542E | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRKDC | c.10368A>C p.L3456F | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PROM1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- PTPN13 | c.2561G>A p.C854Y | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRQ | c.4973C>G p.T1658S (on ENST00000616559; = p.T1616S on NM_001145026.2) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PYGB | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 10/327 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); called by muse, mutect2
- RANBP3L | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- SAP130 | c.3114dup p.V1039Sfs*26 | Frame Shift Ins (INS) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- SH3YL1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A12 | c.2018T>A p.I673N (on ENST00000377369 / NM_001145195.2; = p.I636N on NM_152725.3) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SNX10 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SOGA3 | c.2835dup p.V946Cfs*28 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- SPANXN1 | c.102A>C p.L34F | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.958); called by muse, mutect2
- STARD9 | c.1014C>A p.D338E | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNGAP1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 211/504 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TADA1 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- TENM3 | c.7396T>G p.S2466A | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TEX38 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TEX52 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- TGS1 | c.2408_2409insG p.Y803* | Nonsense Mutation (INS) | VAF 25/167 reads (15%) | called by mutect2, pindel, varscan2
- TMX4 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNPO1 | c.204A>C p.E68D | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TRAPPC12 | c.1813G>C p.D605H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TRO | c.2717G>C p.S906T | Missense Mutation (SNP) | VAF 112/431 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRPC4AP | c.316T>C p.S106P | Missense Mutation (SNP) | VAF 110/134 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TSSK2 | c.946G>C p.G316R | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- TTN | c.100075G>A p.E33359K (on ENST00000591111; = p.E25935K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/458 reads (6%) | PolyPhen benign (0.337); called by muse, mutect2
- TTN | c.80275G>C p.E26759Q (on ENST00000591111; = p.E19335Q on NM_003319.4) | Missense Mutation (SNP) | VAF 107/379 reads (28%) | PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TUSC3 | c.937+2T>G p.X313_splice | Splice Site (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- UGGT2 | c.1971_1972insG p.F658Vfs*7 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- USH2A | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP1 | c.346A>C p.I116L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- WNT5B | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFP92 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ZNF461 | c.332T>A p.L111* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- ZNF700 | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY1 | c.609C>G p.V203= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- ADGRG4 | c.3366T>G p.A1122= | Silent (SNP) | VAF 58/235 reads (25%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.2112G>A p.G704= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs997990728; called by muse, mutect2, varscan2
- AGBL1 | c.753G>A p.K251= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV101408060; called by muse, mutect2, varscan2
- AHCTF1 | c.3651T>G p.A1217= (on ENST00000366508; = p.A1191= on NM_015446.5) | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- ASH1L | c.259T>C p.L87= | Silent (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- CALR3 | c.24C>G p.L8= | Silent (SNP) | VAF 118/315 reads (37%) | catalogued as rs1188580969; called by muse, mutect2, varscan2
- CHST3 | c.333G>A p.G111= | Silent (SNP) | VAF 122/471 reads (26%) | called by muse, mutect2, varscan2
- CST1 | c.201G>A p.P67= | Silent (SNP) | VAF 33/451 reads (7%) | catalogued as rs766339492; called by muse, mutect2
- DDIT4 | c.384C>T p.G128= | Silent (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- DLG3 | c.1251A>G p.G417= (on ENST00000374360 / NM_021120.4; = p.G80= on NM_020730.3) | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as COSV99529584; called by muse, mutect2, varscan2
- DLX1 | c.348C>A p.G116= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2
- EP400 | c.6868C>T p.L2290= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as rs1406086537, COSV100201881; called by muse, mutect2
- EPHA8 | c.747G>C p.A249= | Silent (SNP) | VAF 73/249 reads (29%) | catalogued as COSV51282304; called by muse, mutect2, varscan2
- FAM171A1 | c.2373G>A p.L791= | Silent (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2, varscan2
- GPR45 | c.966C>T p.I322= | Silent (SNP) | VAF 24/247 reads (10%) | catalogued as rs758939694, COSV51524369, COSV99306698; called by muse, mutect2
- HOXD12 | c.294T>G p.A98= | Silent (SNP) | VAF 104/415 reads (25%) | called by muse, varscan2
- HS6ST2 | c.63G>A p.A21= | Silent (SNP) | VAF 111/243 reads (46%) | called by muse, mutect2, varscan2
- LRRC4 | c.387G>A p.E129= | Silent (SNP) | VAF 24/378 reads (6%) | called by muse, mutect2
- LRWD1 | c.939G>C p.V313= | Silent (SNP) | VAF 133/317 reads (42%) | called by muse, mutect2, varscan2
- MAGEB1 | c.726T>C p.R242= | Silent (SNP) | VAF 90/354 reads (25%) | called by muse, mutect2, varscan2
- MAP3K20 | c.465T>G p.S155= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- MED15 | c.1374C>T p.P458= (on ENST00000263205 / NM_001003891.3; = p.P418= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/255 reads (38%) | catalogued as rs773055536; called by muse, mutect2, varscan2
- NFATC2 | c.1170G>A p.V390= | Silent (SNP) | VAF 101/211 reads (48%) | called by muse, mutect2, varscan2
- NOVA1 | c.726A>G p.Q242= | Silent (SNP) | VAF 141/565 reads (25%) | called by muse, mutect2, varscan2
- NUMA1 | c.5859T>C p.D1953= | Silent (SNP) | VAF 35/96 reads (36%) | called by muse, mutect2, varscan2
- NWD1 | c.744C>T p.R248= | Silent (SNP) | VAF 132/376 reads (35%) | catalogued as rs377186225; called by muse, varscan2
- OR5I1 | c.255C>T p.V85= | Silent (SNP) | VAF 88/310 reads (28%) | catalogued as COSV56885929; called by muse, mutect2, varscan2
- PAK3 | c.291C>T p.G97= (on ENST00000262836 / NM_001324328.2; = p.G118= on NM_001128168.3) | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- PCNT | c.1785G>A p.A595= | Silent (SNP) | VAF 149/387 reads (39%) | catalogued as rs887014065; called by muse, mutect2, varscan2
- PIGO | c.2463G>C p.L821= | Silent (SNP) | VAF 31/659 reads (5%) | called by muse, mutect2
- PIP5KL1 | c.168G>A p.T56= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as rs953650772; called by muse, mutect2, varscan2
- PLPPR3 | c.630G>A p.L210= | Silent (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- PRKDC | c.1308G>A p.E436= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV58059974; called by muse, mutect2
- RYR2 | c.9894G>A p.R3298= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- SGO2 | c.2697T>C p.N899= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- ST18 | c.2319C>T p.C773= | Silent (SNP) | VAF 48/256 reads (19%) | catalogued as rs369209561; called by muse, mutect2, varscan2
- TRRAP | c.10047C>T p.S3349= (on ENST00000359863 / NM_001244580.1; = p.S3320= on NM_003496.3) | Silent (SNP) | VAF 57/271 reads (21%) | catalogued as rs1048482022, COSV100723218; called by muse, mutect2, varscan2
- ULK1 | c.2463G>A p.G821= | Silent (SNP) | VAF 71/260 reads (27%) | catalogued as rs764410520; called by muse, mutect2, varscan2
- USH2A | c.9048C>T p.C3016= | Silent (SNP) | VAF 71/164 reads (43%) | catalogued as rs1057519208, COSV56361793; called by muse, mutect2, varscan2
- VN1R2 | c.1101C>T p.L367= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- WNK2 | c.4095G>A p.V1365= | Silent (SNP) | VAF 55/423 reads (13%) | called by muse, mutect2
- ZNF467 | c.879C>A p.I293= | Silent (SNP) | VAF 101/566 reads (18%) | called by muse, mutect2, varscan2
- ZNF696 | c.396C>T p.R132= | Silent (SNP) | VAF 51/331 reads (15%) | called by muse, mutect2, varscan2
- AP001122.1 | n.532G>C | RNA (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- BRD1 | c.2360-199C>A | Intron (SNP) | VAF 118/337 reads (35%) | called by muse, mutect2, varscan2
- CHN1 | c.*554A>T | 3'UTR (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2
- CHN1 | c.*552A>G | 3'UTR (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2
- CHRNB1 | c.244-32C>T | Intron (SNP) | VAF 8/176 reads (5%) | catalogued as rs1172312423; called by muse, mutect2
- ERAP2 | chr5:96873525 G>C | 5'Flank (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- FHOD3 | chr18:36297796 del GCTAACCCCGGG | 5'Flank (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel
- FSCN3 | c.144+573C>G | Intron (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- IQANK1 | c.175+3916_175+3922dup | Intron (INS) | VAF 11/83 reads (13%) | called by mutect2, varscan2
- MRPL27 | c.240+13G>A | Intron (SNP) | VAF 38/117 reads (32%) | catalogued as rs369076431; called by muse, mutect2, varscan2
- MRPS5 | c.763+31G>C | Intron (SNP) | VAF 89/295 reads (30%) | called by muse, mutect2, varscan2
- NEB | c.11602-15683C>T | Intron (SNP) | VAF 24/213 reads (11%) | called by muse, mutect2
- PANK4 | c.207+72G>A | Intron (SNP) | VAF 79/194 reads (41%) | catalogued as rs770970296, COSV65867134; called by muse, mutect2, varscan2
- PHKA2 | c.3283-11del | Intron (DEL) | VAF 52/294 reads (18%) | called by mutect2, pindel, varscan2
- PHKA2 | c.-40C>T | 5'UTR (SNP) | VAF 128/318 reads (40%) | called by muse, mutect2, varscan2
- PTCH1 | c.3449+24C>T | Intron (SNP) | VAF 24/534 reads (4%) | called by muse, mutect2
- RAB18 | c.*3960G>A | 3'UTR (SNP) | VAF 73/261 reads (28%) | called by muse, mutect2, varscan2
- RBM25 | c.867+546G>C | Intron (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1636G>C | 3'UTR (SNP) | VAF 75/200 reads (38%) | called by muse, mutect2, varscan2
- TRIM66 | c.-5C>T | 5'UTR (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.35374+567_35374+568insC | Intron (INS) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- UCHL5 | c.945+672A>T | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- VMA21 | chrX:151396994 C>T | 5'Flank (SNP) | VAF 110/237 reads (46%) | called by muse, mutect2, varscan2
- ZWINT | c.-14C>A | 5'UTR (SNP) | VAF 25/109 reads (23%) | catalogued as rs762388883, COSV100571521; called by muse, mutect2, varscan2
